Somatic mutation profile of tumor specimen TCGA-RW-A67Y-01A (aliquot TCGA-RW-A67Y-01A-11D-A35D-08) from TCGA case TCGA-RW-A67Y, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.1 years (15,729 days).
Specimen TCGA-RW-A67Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4244ad5d-7b9a-41d4-88cf-f4b007a80505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A67Y-10A (Blood Derived Normal), aliquot TCGA-RW-A67Y-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2085a923-02b6-414b-b79f-4a5d90f97dab

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKH | c.2590A>G p.K864E | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1318638751; called by muse, mutect2, varscan2
- LMTK2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs772440680, COSV52005120; called by muse, mutect2, varscan2
- MCHR2 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs1054565517; called by muse, mutect2
- NF1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 39/50 reads (78%) | catalogued as CM1311454, COSV62224610; called by muse, mutect2, varscan2
- ATF7IP | c.1939G>C p.A647P | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SNRPD2 | c.106_109del p.V36Rfs*20 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by pindel, varscan2
- GPR83 | c.1164G>A p.K388= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- MAP4K3 | c.1843C>T p.L615= | Silent (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- UGT2B17 | c.1437C>G p.V479= | Silent (SNP) | VAF 102/113 reads (90%) | catalogued as rs1222321800, COSV58501148; called by muse, mutect2, varscan2
- ZNF683 | c.1374C>A p.T458= (on ENST00000403843; = p.T438= on NM_173574.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
